Gene-level copy-number profile of specimen HCM-SANG-1095-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-1095-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-1095-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e3bed39-cd79-4c35-a116-b04b7df351e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1095-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/49247004-1652-4b5c-bfaf-3d47efc04a83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,235; copy number 2: 29,558; copy number 3: 20,648; copy number 4: 5,538; copy number 5: 366; copy number 6: 28; copy number 7: 16.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:46,372,855–46,487,141, 1 gene: NSFP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 410 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,358,177, 3 genes, copy number 5 (within-gene range 5–6): UGT2B28, AC114786.3, AC114786.2.
- chr4:69,408,828–69,423,164, 1 gene, copy number 5 (within-gene range 3–5): UGT2B24P.
- chr8:24,912,165–25,507,911, 15 genes, copy number 5: AF106564.1, NEFM, NEFL, MIR6841, AC107373.2, AC107373.1, AC107373.3, AC073581.1, DOCK5, AC091185.2, MIR6876, GNRH1, AC091185.1, KCTD9, CDCA2.
- chr8:31,033,788–34,346,731, 44 genes, copy number 5 (within-gene range 1–5): WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1.
- chr8:38,099,471–38,973,912, 32 genes, copy number 5–7: AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1.
- chr8:39,743,735–41,309,473, 24 genes, copy number 5: ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr8:51,810,110–52,022,974, 7 genes, copy number 5: AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3.
- chr12:12,310–991,190, 28 genes, copy number 6 (within-gene range 4–6): DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:64,222,337–64,397,065, 1 gene, copy number 5 (within-gene range 3–5): AC012158.1.
- chr12:64,264,762–73,208,317, 177 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:123,973,241–124,316,024, 1 gene, copy number 5 (within-gene range 3–5): RFLNA.
- chr12:124,206,228–127,372,669, 72 genes, copy number 5 (broad region; genes not listed).
- chr18:22,347,846–22,587,227, 4 genes, copy number 5: AC027449.1, CTAGE1, ATP7BP1, RPS4XP18.
- chr19:7,037,748–7,040,179, 1 gene, copy number 5: MBD3L4.

Autosomal genes at a single copy (total copy number 1): 2,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
